Gene-level copy-number profile of tumor specimen TCGA-EE-A2MU-06A from TCGA case TCGA-EE-A2MU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.8 years (27,688 days).
Specimen TCGA-EE-A2MU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.fab97181-d27a-42d2-81e8-220373d79101.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3af0c156-cec8-4a35-b9c0-3acd8e4b0fd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,604; copy number 2: 30,020; copy number 3: 19,252; copy number 4: 7,756; copy number 5: 530; copy number 6: 213; copy number 7: 23; copy number 8: 82; copy number 11: 238; copy number 13: 6; copy number 14: 67; copy number 16: 6; copy number 19: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MU-06A-21D-A194-01): tumor purity 0.29, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,140 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,921,077–90,115,402, 869 genes, copy number 5–19 (broad region; genes not listed).
- chr6:60,719,222–85,427,966, 271 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 486. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
